CCDI case PBBYYH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/f6bedaac-f738-4b7d-96a3-27b578af5eef

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 1.9 years (685 days).

Biospecimens (3 samples)
- Sample 0DLDZ9: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLDZE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLDZO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
